TCGA case TCGA-AX-A05Y — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cbe0bd4a-02b7-43e7-b08e-2b0f13560eaf

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Alive.

Diagnoses (2)
1. Endometrioid adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 57.2 years (20,904 days); Year of diagnosis: 2004; Method of diagnosis: Biopsy; FIGO stage: Stage IB; FIGO staging edition year: 1988; Tumor grade: G1; Prior treatment: No; Residual disease: R0; Days to last follow up: 2,684 days (7.3 years).
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 24.
   Pathology details: Percent tumor invasion: 50.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 6.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded, whether given is unknown: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Age at diagnosis: 57.8 years (21,098 days); Days to diagnosis: 194 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (4 entries)
- Day 194 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 2,191 days (6.0 years); Disease response: Tumor Free.
- Days to follow up: 2,684 days (7.3 years); Disease response: Tumor Free.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Menopause status: Postmenopausal; Number of pregnancies: 4+; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Diabetes, NOS / Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 92 kg; Height: 166 cm; BMI: 33.4.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AX-A05Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 230 mg.
  Slide TCGA-AX-A05Y-01A-01-BS1: Section location: Bottom; Percent tumor cells: 96; Percent tumor nuclei: 96; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 2; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 2.
  Slide TCGA-AX-A05Y-01A-01-TS1: Section location: Top; Percent tumor cells: 92; Percent tumor nuclei: 92; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 5.
- Sample TCGA-AX-A05Y-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AX-A05Y-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-AX-A05Y-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 140 mg.
  Slide TCGA-AX-A05Y-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Method initial path diagnosis: Office Endometrial Biopsy; Surgical approach at diagnosis: open.
- Follow-up form 1: Hypertension diagnosis: Yes; Diabetes diagnosis indicator: Yes; History colorectal cancer: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; New tumor event surgery: Yes; New tumor event procedure: Other Method, Specify Below; New tumor event procedure other: Whipple Procedure; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,684 days; disease-specific survival: no event (censored), 2,684 days; disease-free interval: event (new tumor event after initially disease-free), 194 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 194 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AX-A05Y-01A-11D-A00X-01): tumor purity 0.98, ploidy 2.03, whole-genome doublings 0.
